CPTAC case C3L-04213 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/029e2f23-a4a4-4529-a428-336025bcc059

Demographics
Sex at birth: female; Race: white; Year of birth: 1981; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Occipital lobe; Age at diagnosis: 37.4 years (13,671 days); Year of diagnosis: 2018; Last known disease status: Tumor free; Days to last known disease status: 1,450 days (4.0 years); Progression or recurrence: no; Days to last follow up: 1,450 days (4.0 years).
   Pathology details: Greatest tumor dimension: 7 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 405 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 738 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 738 days (2.0 years); Disease response: Complete Response.
- Days to follow up: 1,036 days (2.8 years); Disease response: Tumor Free.
- Days to follow up: 1,450 days (4.0 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 72 kg; Height: 167 cm; BMI: 25.82.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04213-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 234 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04213-21: Section location: Occipital Lobe; Percent tumor nuclei: 85; Percent necrosis: 10.
- Sample C3L-04213-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
